Somatic mutation profile of tumor specimen TCGA-ZB-A96M-01A (aliquot TCGA-ZB-A96M-01A-11D-A428-09) from TCGA case TCGA-ZB-A96M, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 56.5 years (20,623 days).
Specimen TCGA-ZB-A96M-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3464516-bb32-40f9-956d-12f172759b18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A96M-10A (Blood Derived Normal), aliquot TCGA-ZB-A96M-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e69512a4-7ccc-41d3-96d2-e7055b79d70b

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 12, Silent 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 64/480 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- DNAH17 | c.9517G>A p.A3173T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs759137847, COSV67757976; called by mutect2, varscan2
- FZD10 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.453); catalogued as rs1173644283; called by muse, mutect2
- KIDINS220 | c.4802A>G p.N1601S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as rs1224245621; called by muse, mutect2
- PCLO | c.141G>C p.Q47H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.351); catalogued as COSV100432997; called by muse, mutect2, varscan2
- PROX1 | c.1222C>T p.R408C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1346299564, COSV54778859; called by muse, mutect2
- ZNF649 | c.1469_1470del p.V490Gfs*8 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs1389619990; called by pindel, varscan2
- COG5 | c.2026C>A p.Q676K (on ENST00000347053 / NM_001379512.1; = p.Q697K on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.936); called by muse, mutect2
- DAGLA | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- DYRK2 | c.1009G>T p.D337Y (on ENST00000344096 / NM_006482.3; = p.D264Y on NM_003583.4) | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- KCNV2 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PIK3C2B | c.3176C>T p.S1059F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF776 | c.731T>G p.F244C | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- COLGALT2 | c.1284G>A p.E428= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs200107460; called by muse, mutect2, varscan2
- EGLN3 | c.372C>T p.C124= | Silent (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- MKI67 | c.4107T>C p.T1369= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
